CPTAC case C3L-00189 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b595f6fa-22b0-4646-9dfd-c49f53623587

Demographics
Sex at birth: female; Year of birth: 1948; Vital status: Dead; Days to death: 1,036 days (2.8 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Canada.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 68.3 years (24,958 days); Year of diagnosis: 2016; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 1,036 days (2.8 years); Progression or recurrence: yes; Days to recurrence: 424 days (1.2 years); Days to last follow up: 1,036 days (2.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.7 cm (a second GDC size field records 6.3 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 13; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 353 days; Disease response: Stable Disease; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 867 days (2.4 years); Disease response: Progressive Disease; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 991 days (2.7 years); Disease response: Progressive Disease; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 1,036 days (2.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 424 days (1.2 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 84.5 kg; Height: 157 cm; BMI: 34.28; Comorbidities: Hypertension.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Cigarettes per day: 12; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00189-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 59 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00189-21: Section location: Head; Percent tumor nuclei: 50; Percent necrosis: 0.
- Sample C3L-00189-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 116 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00189-22: Section location: Head; Percent tumor nuclei: 20; Percent necrosis: 0.
- Sample C3L-00189-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -7 days; Initial weight: 55 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00189-23: Section location: Head; Percent tumor nuclei: 25; Percent necrosis: 20.
- Sample C3L-00189-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
- Sample C3L-00189-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
